FM case AD14708 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/af4536a7-dc47-446a-bb43-6da9e25476ab

Male, 48.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the ureter. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
